Gene-level copy-number profile of tumor specimen TCGA-DD-A3A3-01A from TCGA case TCGA-DD-A3A3, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 45.7 years (16,708 days).
Specimen TCGA-DD-A3A3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.59174338-a1f6-47f2-9f6b-730ba1015438.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A3A3-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7e6d0edc-68b1-47c9-8d4a-d9191f030aae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,511; copy number 2: 45,822; copy number 3: 5,112; copy number 4: 2,604; copy number 5: 103; copy number 9: 414; copy number 10: 1,254.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A3A3-01A-11D-A22E-01): tumor purity 0.78, ploidy 2.35, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,771 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:28,345,590–28,890,242, 14 genes, copy number 9: ZNF395, FBXO16, AC025871.3, AC025871.2, RNU6-178P, AC025871.1, FZD3, MIR4288, RNA5SP259, EXTL3, EXTL3-AS1, INTS9, INTS9-AS1, AC040975.1.
- chr8:28,915,579–28,955,955, 2 genes, copy number 9: Metazoa_SRP, HMBOX1-IT1.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5–10 (within-gene range 1–10) (broad region; genes not listed).
- chr17:18,107,334–21,043,760, 189 genes, copy number 9 (broad region; genes not listed).
- chr17:21,614,487–22,606,703, 32 genes, copy number 5 (within-gene range 1–5): AC233702.1, AC233702.4, AC233702.9, KCNJ18, AC243725.1, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1.

Autosomal genes at a single copy (total copy number 1): 2,124. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
